Somatic mutation profile of tumor specimen ALCH-B1IT-TTP1-A (aliquot ALCH-B1IT-TTP1-A-1-0-D-A714-36) from ALCHEMIST case ALCH-B1IT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.9 years (22,987 days).
Specimen ALCH-B1IT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e1e4bd1-6ed5-44fe-836b-db11902f3d08.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1IT-NB1-A (Blood Derived Normal), aliquot ALCH-B1IT-NB1-A-1-0-D-A714-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe800020-d4cf-43d6-af2c-b8d8e369946e

The open-access MAF lists 1,235 somatic variants for this specimen: 858 protein-altering or splice-affecting, 239 silent, 138 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 730, Silent 239, Intron 63, Nonsense Mutation 57, RNA 34, Frame Shift Del 29, 3'UTR 20, Splice Region 16, Splice Site 15, 5'UTR 10, 5'Flank 7, Frame Shift Ins 6.

Variants (750 of 1,235; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 200/444 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NBN | c.2161G>T p.E721* | Nonsense Mutation (SNP) | VAF 205/606 reads (34%) | catalogued as rs1064795816, COSV55376328; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.673-1G>T p.X225_splice | Splice Site (SNP) | VAF 111/424 reads (26%) | hotspot (GDC flag); catalogued as rs878854073, CS011061, COSV52662773, COSV52705331, COSV52707963, COSV53154363; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCD2 | c.1738C>A p.L580M | Missense Mutation (SNP) | VAF 78/201 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58053290; called by muse, mutect2, varscan2
- AC010255.2 | c.78G>T p.E26D | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs1473476479; called by muse, mutect2
- ACTRT2 | c.400C>A p.P134T | Missense Mutation (SNP) | VAF 38/179 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65759220; called by muse, mutect2, varscan2
- ADAMTS12 | c.4601G>T p.S1534I | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.12); catalogued as COSV61273116; called by muse, mutect2, varscan2
- ADCY1 | c.2003C>A p.T668K | Missense Mutation (SNP) | VAF 71/428 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as COSV52037218; called by muse, mutect2, varscan2
- ADCY9 | c.1261G>T p.D421Y | Missense Mutation (SNP) | VAF 39/222 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778333072, COSV99569267; called by muse, mutect2, varscan2
- ADGB | c.4204G>T p.A1402S | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV58849329; called by muse, mutect2, varscan2
- ADGRA1 | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs1183242981, COSV66924954, COSV66925397; called by muse, mutect2, varscan2
- ADGRB3 | c.2623G>T p.G875C | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.876); catalogued as COSV53262751; called by muse, mutect2, varscan2
- ADGRV1 | c.4819C>G p.H1607D | Missense Mutation (SNP) | VAF 29/205 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.533); catalogued as COSV67979877; called by muse, mutect2, varscan2
- ADH1C | c.40G>C p.V14L | Missense Mutation (SNP) | VAF 27/278 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV72463687; called by muse, mutect2, varscan2
- ADPRH | c.221del p.P74Lfs*3 | Frame Shift Del (DEL) | VAF 80/419 reads (19%) | catalogued as COSV63695578; called by mutect2, pindel, varscan2
- ANK1 | c.4784C>A p.A1595D | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.282); catalogued as COSV55879798; called by muse, mutect2, varscan2
- ANK1 | c.1888del p.A630Pfs*7 | Frame Shift Del (DEL) | VAF 76/318 reads (24%) | catalogued as COSV55874846; called by mutect2, pindel*, varscan2
- ANO1 | c.2284C>T p.R762C | Missense Mutation (SNP) | VAF 30/418 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs746632501; called by muse, mutect2
- ARSI | c.1504G>T p.V502L | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV60817083; called by muse, mutect2, varscan2
- ATAD2 | c.2569G>A p.V857M | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as rs1433196973; called by muse, mutect2, varscan2
- ATP8A1 | c.1602A>T p.S534= | Splice Region (SNP) | VAF 52/261 reads (20%) | catalogued as COSV52549393; called by muse, mutect2, varscan2
- BAZ2B | c.3738G>T p.W1246C | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); catalogued as COSV54276500; called by muse, varscan2
- BDH2 | c.46C>A p.Q16K | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV56478520; called by muse, mutect2, varscan2
- BMX | c.1967G>T p.R656L | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99382586; called by muse, mutect2, varscan2
- C20orf203 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as rs1169366146; called by muse, mutect2, varscan2
- C4orf50 | c.340C>A p.Q114K (on ENST00000324058; = p.Q1346K on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.124); catalogued as COSV60690956; called by muse, mutect2, varscan2
- CACNA2D1 | c.1975A>T p.T659S (on ENST00000356253 / NM_001366867.1; = p.T647S on NM_000722.4) | Missense Mutation (SNP) | VAF 94/391 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.852); catalogued as COSV62375295; called by muse, mutect2, varscan2
- CBY3 | c.121C>A p.R41S | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.412); catalogued as rs1405223711; called by muse, mutect2, varscan2
- CCDC168 | c.3348G>T p.M1116I | Missense Mutation (SNP) | VAF 21/175 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.07); catalogued as rs777471951; called by muse, mutect2, varscan2
- CDH10 | c.1063G>T p.V355L | Missense Mutation (SNP) | VAF 67/311 reads (22%) | SIFT tolerated (0.88); PolyPhen benign (0.017); catalogued as COSV52584202; called by muse, mutect2, varscan2
- CDH7 | c.463G>C p.D155H | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.95); catalogued as COSV59891200; called by muse, mutect2, varscan2
- CENPL | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.058); catalogued as rs1557846752; called by muse, mutect2, varscan2
- CEP126 | c.1059G>T p.L353F | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.222); catalogued as rs145904743, COSV54825543; called by muse, mutect2, varscan2
- CHRDL1 | c.677G>T p.R226L (on ENST00000372045; = p.R232L on NM_145234.4) | Missense Mutation (SNP) | VAF 67/179 reads (37%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.982); catalogued as COSV54323868, COSV54325580; called by muse, mutect2, varscan2
- CHRM3 | c.53C>A p.S18Y | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.177); catalogued as rs369433508, COSV55094936; called by muse, mutect2, varscan2
- CIDEA | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.946); catalogued as rs147827259; called by muse, mutect2, varscan2
- CNTN6 | c.1796G>T p.G599V | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765761562; called by muse, mutect2, varscan2
- CNTNAP2 | c.258G>T p.Q86H | Missense Mutation (SNP) | VAF 124/550 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62152612; called by muse, varscan2
- CNTNAP2 | c.259G>T p.V87F | Missense Mutation (SNP) | VAF 122/548 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV100667201; called by muse, varscan2
- COL14A1 | c.5207G>T p.G1736V | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52860832; called by muse, mutect2, varscan2
- COL3A1 | c.959G>C p.R320P | Missense Mutation (SNP) | VAF 69/482 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV58597820; called by muse, mutect2, varscan2
- COL5A2 | c.761G>T p.R254L | Missense Mutation (SNP) | VAF 79/417 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV100880772; called by muse, mutect2, varscan2
- COL6A1 | c.850G>T p.G284* | Nonsense Mutation (SNP) | VAF 11/75 reads (15%) | catalogued as CM050214, CM1310878, COSV62612600; called by muse, mutect2
- COL6A6 | c.4907G>T p.G1636V | Missense Mutation (SNP) | VAF 72/388 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs927359924, COSV62022245; called by muse, mutect2, varscan2
- COQ8B | c.959G>T p.R320L | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); catalogued as COSV54687518; called by muse, mutect2, varscan2
- CPS1 | c.944A>G p.N315S | Missense Mutation (SNP) | VAF 73/407 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1239909677; called by muse, mutect2, varscan2
- CRACD | c.1985C>A p.A662E | Missense Mutation (SNP) | VAF 60/234 reads (26%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.773); catalogued as COSV51716434, COSV51717006; called by muse, mutect2, varscan2
- CRB1 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 61/404 reads (15%) | catalogued as COSV66341337; called by muse, mutect2, varscan2
- CRISP3 | c.580C>A p.L194I (on ENST00000371159 / NM_001368123.1; = p.L176I on NM_006061.4) | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV53819951; called by muse, mutect2, varscan2
- CRYGB | c.251del p.P84Rfs*8 | Frame Shift Del (DEL) | VAF 16/82 reads (20%) | catalogued as rs1559328208, COSV53679868; called by mutect2, pindel
- CSMD2 | c.3287C>A p.A1096D | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99588699; called by muse, mutect2
- CSMD3 | c.6181G>T p.G2061* (on ENST00000297405 / NM_001363185.1; = p.G1957* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 51/483 reads (11%) | catalogued as COSV52121577; called by muse, mutect2, varscan2
- CSMD3 | c.5180G>A p.C1727Y (on ENST00000297405 / NM_001363185.1; = p.C1623Y on NM_052900.3) | Missense Mutation (SNP) | VAF 46/375 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99835646; called by muse, mutect2, varscan2
- CT47B1 | c.757G>T p.E253* | Nonsense Mutation (SNP) | VAF 25/55 reads (45%) | catalogued as COSV100988945; called by muse, mutect2, varscan2
- CUBN | c.1841G>T p.R614I | Missense Mutation (SNP) | VAF 112/496 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV64708340; called by muse, mutect2, varscan2
- DACT1 | c.2087G>A p.R696H | Missense Mutation (SNP) | VAF 62/165 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs773256045; called by muse, mutect2, varscan2
- DCC | c.1819G>T p.G607C | Missense Mutation (SNP) | VAF 63/414 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59121541; called by muse, varscan2
- DDX24 | c.932G>T p.S311I | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.184); catalogued as rs36082609; called by muse, mutect2, varscan2
- DHX38 | c.3659G>T p.R1220L | Missense Mutation (SNP) | VAF 55/218 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.268); catalogued as COSV51701169; called by muse, mutect2, varscan2
- DNAAF1 | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 37/218 reads (17%) | catalogued as rs565199726; called by muse, mutect2, varscan2
- DNAH5 | c.2819C>T p.T940I | Missense Mutation (SNP) | VAF 102/586 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV54244873; called by muse, mutect2, varscan2
- DNAJC10 | c.2087A>G p.Y696C | Missense Mutation (SNP) | VAF 57/288 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs754761068; called by muse, mutect2, varscan2
- DRC7 | c.1501G>T p.D501Y | Missense Mutation (SNP) | VAF 39/242 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV61052877; called by muse, mutect2, varscan2
- DSG1 | c.1016A>T p.Y339F | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as COSV57135672; called by muse, mutect2, varscan2
- DSG3 | c.2386-1G>T p.X796_splice | Splice Site (SNP) | VAF 33/126 reads (26%) | catalogued as rs1204914891; called by muse, mutect2, varscan2
- DYNC1I1 | c.1837C>A p.P613T | Missense Mutation (SNP) | VAF 66/291 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as COSV100268755; called by muse, mutect2, varscan2
- EHD4 | c.884G>C p.R295P | Missense Mutation (SNP) | VAF 62/323 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55004924; called by muse, mutect2, varscan2
- ENG | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as rs1228468026; called by muse, mutect2, varscan2
- ENPEP | c.203C>G p.S68* | Nonsense Mutation (SNP) | VAF 19/141 reads (13%) | catalogued as COSV54450318, COSV54457280; called by muse, mutect2, varscan2
- ENPP3 | c.768G>T p.W256C | Missense Mutation (SNP) | VAF 51/210 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62954519; called by muse, mutect2, varscan2
- EPHB4 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs781488120; called by muse, mutect2, varscan2
- EPHB6 | c.165G>T p.G55= | Splice Region (SNP) | VAF 134/621 reads (22%) | catalogued as rs763119570; called by muse, mutect2, varscan2
- ERICH3 | c.3237G>C p.E1079D | Missense Mutation (SNP) | VAF 94/398 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.503); catalogued as rs1210424037, COSV100443289; called by muse, mutect2, varscan2
- ESPNL | c.2435A>G p.K812R | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.474); catalogued as rs1375531980; called by muse, mutect2, varscan2
- EVX1 | c.740G>T p.W247L | Missense Mutation (SNP) | VAF 61/323 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99763896; called by muse, mutect2, varscan2
- EYA4 | c.1343A>G p.N448S (on ENST00000531901 / NM_001301013.1; = p.N442S on NM_004100.5) | Missense Mutation (SNP) | VAF 154/543 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); catalogued as rs750848162; called by muse, mutect2, varscan2
- EYS | c.1182C>T p.C394= | Splice Region (SNP) | VAF 36/123 reads (29%) | catalogued as rs1311395605; called by muse, mutect2, varscan2
- FAM189B | c.978C>A p.S326R | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs1463492807; called by muse, mutect2, varscan2
- FAM47B | c.599G>T p.R200L | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as COSV61454531; called by muse, mutect2, varscan2
- FAM47B | c.854C>A p.P285Q | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.945); catalogued as COSV61456680; called by muse, mutect2, varscan2
- FAM90A14P | c.712C>G p.R238G | Missense Mutation (SNP) | VAF 84/465 reads (18%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.728); catalogued as rs762790653; called by muse, mutect2, varscan2
- FAT1 | c.12950C>T p.P4317L | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.114); catalogued as rs890879365, COSV101499700; called by muse, mutect2, varscan2
- FERD3L | c.430C>A p.R144S | Missense Mutation (SNP) | VAF 115/447 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51761884, COSV51762932; called by muse, mutect2, varscan2
- FERMT3 | c.1548G>T p.K516N (on ENST00000279227 / NM_178443.3; = p.K512N on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 112/421 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99656547; called by muse, mutect2, varscan2
- FEZ1 | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 82/644 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.025); catalogued as COSV54027148; called by muse, mutect2, varscan2
- FFAR4 | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 67/432 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs748031934; called by muse, mutect2, varscan2
- FGD5 | c.1678G>A p.V560M | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.08); catalogued as rs921634187; called by muse, mutect2, varscan2
- FHL2 | c.10C>A p.R4S | Missense Mutation (SNP) | VAF 34/252 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.048); catalogued as rs536715218, COSV59079388; called by muse, mutect2, varscan2
- FIGN | c.1559G>C p.R520P | Missense Mutation (SNP) | VAF 43/246 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60765614; called by muse, mutect2, varscan2
- FLG | c.3010C>A p.Q1004K | Missense Mutation (SNP) | VAF 61/537 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1486805206, COSV100911942; called by muse, varscan2
- FLG | c.2929C>A p.Q977K | Missense Mutation (SNP) | VAF 104/790 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.431); catalogued as rs144419479; called by muse, varscan2
- FLNC | c.5417C>A p.S1806* | Nonsense Mutation (SNP) | VAF 147/552 reads (27%) | catalogued as COSV57955685; called by muse, mutect2, varscan2
- FLYWCH1 | c.1130G>C p.G377A (on ENST00000253928 / NM_001308068.2; = p.G376A on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.992); catalogued as rs373786669; called by muse, mutect2, varscan2
- FMN2 | c.3278G>T p.G1093V | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.447); catalogued as COSV100144764, COSV100146978; called by muse, varscan2
- FMR1NB | c.392C>A p.P131Q | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100789542, COSV63272986; called by muse, mutect2, varscan2
- FUT6 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 82/242 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); catalogued as rs371098612; called by muse, mutect2, varscan2
- GNS | c.1266C>A p.N422K | Missense Mutation (SNP) | VAF 197/478 reads (41%) | SIFT tolerated (0.62); PolyPhen benign (0.069); catalogued as COSV50694883; called by muse, mutect2, varscan2
- GOLGB1 | c.2391G>T p.Q797H | Missense Mutation (SNP) | VAF 112/608 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs748954371, COSV61470299; called by muse, mutect2, varscan2
- GRID2 | c.2731C>A p.P911T | Missense Mutation (SNP) | VAF 101/627 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.981); catalogued as COSV56207841; called by muse, mutect2, varscan2
- GRID2IP | c.755C>A p.P252Q | Missense Mutation (SNP) | VAF 8/8 reads (100%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); catalogued as rs1413542468; called by mutect2, varscan2
- GRK7 | c.54G>T p.Q18H | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV53824199; called by muse, mutect2, varscan2
- GTF3C2 | c.1453G>T p.G485C | Missense Mutation (SNP) | VAF 45/263 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1177468973; called by muse, mutect2, varscan2
- HELQ | c.2873A>G p.N958S | Missense Mutation (SNP) | VAF 47/262 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.416); catalogued as COSV99787850; called by muse, mutect2, varscan2
- HHIPL1 | c.1810G>T p.E604* | Nonsense Mutation (SNP) | VAF 70/225 reads (31%) | catalogued as COSV100415194; called by muse, mutect2, varscan2
- HPX | c.692G>C p.C231S | Missense Mutation (SNP) | VAF 90/267 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56418747; called by muse, mutect2, varscan2
- HSPG2 | c.9799C>T p.R3267W | Missense Mutation (SNP) | VAF 60/300 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs760029661; called by muse, mutect2, varscan2
- IFNA8 | c.518G>T p.R173I | Missense Mutation (SNP) | VAF 67/294 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66504973; called by muse, mutect2, varscan2
- IGF2BP2 | c.1192C>A p.P398T | Missense Mutation (SNP) | VAF 55/251 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as COSV60483283; called by muse, mutect2, varscan2
- IGKV1D-16 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 102/702 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.102); catalogued as rs1409629064; called by muse, varscan2
- ILDR2 | c.1832C>T p.P611L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs756001347; called by muse, mutect2, varscan2
- INSC | c.869G>T p.R290L | Missense Mutation (SNP) | VAF 105/352 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.79); catalogued as COSV65410379; called by muse, mutect2, varscan2
- IQUB | c.1588G>T p.E530* | Nonsense Mutation (SNP) | VAF 36/155 reads (23%) | catalogued as COSV61239390; called by muse, mutect2, varscan2
- IRF1 | c.385del p.R129Efs*51 | Frame Shift Del (DEL) | VAF 51/354 reads (14%) | catalogued as COSV55376240; called by mutect2, pindel, varscan2
- ITGAM | c.1390G>T p.V464L | Missense Mutation (SNP) | VAF 99/502 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.432); catalogued as COSV99792813; called by muse, mutect2, varscan2
- JHY | c.1698G>T p.Q566H | Missense Mutation (SNP) | VAF 72/323 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV57077231; called by muse, mutect2, varscan2
- JHY | c.2152G>T p.A718S | Missense Mutation (SNP) | VAF 80/297 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs139788166; called by muse, mutect2, varscan2
- JUNB | c.524G>T p.G175V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.441); catalogued as rs972415074; called by muse, mutect2, varscan2
- KCNA4 | c.1577G>T p.G526V | Missense Mutation (SNP) | VAF 72/234 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60252520; called by muse, mutect2, varscan2
- KCNQ2 | c.1003C>A p.P335T | Missense Mutation (SNP) | VAF 87/423 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100610044; called by muse, mutect2, varscan2
- KCTD8 | c.196C>G p.P66A | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs534771289; called by muse, mutect2, varscan2
- KEL | c.72G>T p.W24C | Missense Mutation (SNP) | VAF 200/781 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.334); catalogued as COSV62334910; called by mutect2, varscan2
- KIAA1549L | c.2895G>T p.Q965H (on ENST00000321505; = p.Q1262H on NM_012194.3) | Missense Mutation (SNP) | VAF 84/570 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV55777069; called by muse, mutect2, varscan2
- KIR2DL1 | c.330G>T p.Q110H | Missense Mutation (SNP) | VAF 88/233 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as COSV99383794; called by muse, mutect2, varscan2
- KIR3DL3 | c.542C>A p.S181Y | Missense Mutation (SNP) | VAF 53/234 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.172); catalogued as COSV52545674; called by muse, mutect2, varscan2
- KLHL1 | c.1798G>A p.G600S | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.206); catalogued as rs746861654, COSV64776272; called by muse, mutect2, varscan2
- KLHL22 | c.1621G>C p.V541L | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1404226623; called by muse, mutect2, varscan2
- KLHL5 | c.2225G>A p.C742Y | Missense Mutation (SNP) | VAF 86/424 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as rs1336080053, COSV54677484; called by muse, mutect2, varscan2
- KPRP | c.580del p.Q194Sfs*17 | Frame Shift Del (DEL) | VAF 72/483 reads (15%) | catalogued as COSV100908686; called by mutect2, pindel, varscan2
- KRTAP13-4 | c.88G>C p.V30L | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as rs1252160586; called by muse, mutect2, varscan2
- LAMA2 | c.2957G>T p.W986L | Missense Mutation (SNP) | VAF 181/727 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.129); catalogued as COSV70357241; called by muse, mutect2, varscan2
- LECT2 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 29/311 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs753311386, COSV50846986; called by muse, mutect2
- LENG9 | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 41/114 reads (36%) | catalogued as COSV56618259; called by muse, mutect2, varscan2
- LILRB2 | c.1685A>G p.Y562C | Missense Mutation (SNP) | VAF 82/318 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100079523; called by muse, mutect2, varscan2
- LRP1B | c.12116+1del p.X4039_splice | Splice Site (DEL) | VAF 65/230 reads (28%) | catalogued as COSV67182617; called by mutect2, pindel, varscan2
- LRP1B | c.12029T>A p.V4010E | Missense Mutation (SNP) | VAF 93/619 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV101258774; called by muse, mutect2, varscan2
- LRRC7 | c.3652C>A p.Q1218K (on ENST00000651989 / NM_001370785.2; = p.Q1185K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 89/372 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs757845149; called by muse, mutect2, varscan2
- LRRIQ4 | c.1432C>A p.P478T | Missense Mutation (SNP) | VAF 105/499 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs374309402; called by muse, mutect2, varscan2
- LRRTM2 | c.141C>A p.C47* | Nonsense Mutation (SNP) | VAF 50/324 reads (15%) | catalogued as COSV51220710; called by muse, mutect2, varscan2
- MAGEA11 | c.209C>A p.A70D | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.486); catalogued as COSV100290531; called by muse, mutect2, varscan2
- MAGEB18 | c.28C>A p.R10S | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99082041; called by muse, mutect2, varscan2
- MAGI2 | c.2152C>A p.P718T | Missense Mutation (SNP) | VAF 130/422 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV62633309; called by muse, mutect2, varscan2
- MC2R | c.697G>T p.A233S | Missense Mutation (SNP) | VAF 131/560 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.529); catalogued as CM021633; called by muse, mutect2
- MC3R | c.527G>A p.G176D | Missense Mutation (SNP) | VAF 87/490 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54764742; called by muse, mutect2, varscan2
- MED15 | c.1272G>T p.Q424H | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs1194391936; called by muse, mutect2, varscan2
- MEGF10 | c.745G>T p.V249F | Missense Mutation (SNP) | VAF 55/342 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.491); catalogued as COSV57253128; called by muse, mutect2, varscan2
- MEPCE | c.566G>A p.G189D | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52768766; called by muse, mutect2, varscan2
- MLLT10 | c.281G>A p.R94K | Missense Mutation (SNP) | VAF 72/434 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV100307392; called by mutect2, varscan2
- MMP26 | c.427C>A p.Q143K | Missense Mutation (SNP) | VAF 34/274 reads (12%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as rs770471115; called by muse, mutect2, varscan2
- MUC22 | c.3323C>T p.A1108V | Missense Mutation (SNP) | VAF 268/585 reads (46%) | SIFT tolerated (1); catalogued as rs1368793095; called by muse, mutect2, varscan2
- MUTYH | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 116/654 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.276); catalogued as rs1553131563, COSV62742667; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH15 | c.3850G>T p.D1284Y | Missense Mutation (SNP) | VAF 96/448 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs779129105; called by muse, mutect2, varscan2
- MYH7 | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 133/542 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62521211; called by muse, mutect2, varscan2
- MYLK | c.596T>A p.V199D | Missense Mutation (SNP) | VAF 206/873 reads (24%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.915); catalogued as COSV60605477; called by muse, mutect2, varscan2
- MYO3A | c.2188G>T p.E730* | Nonsense Mutation (SNP) | VAF 48/221 reads (22%) | catalogued as COSV56319310, COSV56336606; called by muse, mutect2, varscan2
- NAA16 | c.1870C>T p.Q624* | Nonsense Mutation (SNP) | VAF 69/384 reads (18%) | catalogued as COSV65127312, COSV65129318; called by muse, mutect2, varscan2
- NAALAD2 | c.1550G>T p.R517I | Missense Mutation (SNP) | VAF 84/326 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.487); catalogued as COSV58959701; called by muse, varscan2
- NAV3 | c.2353C>T p.L785F | Missense Mutation (SNP) | VAF 113/310 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs267603688; called by muse, mutect2, varscan2
- NBAS | c.3752A>T p.Q1251L | Missense Mutation (SNP) | VAF 127/742 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.346); catalogued as rs1170510051; called by muse, mutect2, varscan2
- NCBP3 | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 87/393 reads (22%) | catalogued as COSV50109403; called by muse, mutect2, varscan2
- NCK2 | c.410G>C p.R137P | Missense Mutation (SNP) | VAF 44/221 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV51891230; called by muse, mutect2, varscan2
- NCSTN | c.1795-4G>T | Splice Region (SNP) | VAF 92/692 reads (13%) | catalogued as rs747860349; called by muse, mutect2, varscan2
- NDST3 | c.353C>A p.P118Q | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99631946; called by muse, mutect2, varscan2
- NEK1 | c.862A>G p.I288V | Missense Mutation (SNP) | VAF 91/420 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1339992357; called by muse, mutect2, varscan2
- NEUROG1 | c.221G>C p.R74P | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as rs1341784150; called by muse, varscan2
- NFASC | c.319G>T p.G107W (on ENST00000339876 / NM_001378329.1; = p.G101W on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/277 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100364820, COSV58366690; called by muse, mutect2, varscan2
- NFRKB | c.1709G>T p.R570L (on ENST00000446488 / NM_001143835.2; = p.R595L on NM_006165.3) | Missense Mutation (SNP) | VAF 57/179 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs376035619, COSV100451787; called by muse, mutect2, varscan2
- NME8 | c.1269G>T p.M423I | Missense Mutation (SNP) | VAF 101/723 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV52254009; called by muse, mutect2, varscan2
- NMUR2 | c.807G>T p.M269I | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as rs970290833; called by muse, varscan2
- NOP58 | c.867G>T p.M289I | Missense Mutation (SNP) | VAF 44/333 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs776669063; called by muse, mutect2, varscan2
- NPHS1 | c.885G>T p.Q295H | Missense Mutation (SNP) | VAF 109/374 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV100800186; called by muse, mutect2, varscan2
- NRCAM | c.47G>T p.R16I | Missense Mutation (SNP) | VAF 60/371 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV61030439, COSV61035172; called by muse, mutect2, varscan2
- NRXN1 | c.2008C>G p.P670A | Missense Mutation (SNP) | VAF 82/388 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs762326241; ClinVar: uncertain significance; called by muse, varscan2
- NUGGC | c.1484C>T p.A495V | Missense Mutation (SNP) | VAF 63/221 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374912166; called by muse, mutect2, varscan2
- OASL | c.277A>T p.S93C | Missense Mutation (SNP) | VAF 144/326 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV57478777; called by muse, mutect2, varscan2
- OBSCN | c.3646G>T p.V1216F | Missense Mutation (SNP) | VAF 52/391 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as rs771042239; called by muse, mutect2, varscan2
- OR10J1 | c.847C>A p.L283I | Missense Mutation (SNP) | VAF 89/340 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV71128193; called by muse, mutect2, varscan2
- OR11G2 | c.872G>T p.G291V | Missense Mutation (SNP) | VAF 52/328 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62132490; called by muse, mutect2, varscan2
- OR4A15 | c.560G>T p.C187F | Missense Mutation (SNP) | VAF 40/292 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs200768577; called by muse, varscan2
- OR4A15 | c.583C>A p.L195I | Missense Mutation (SNP) | VAF 78/346 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.4); catalogued as rs753902951, COSV100123895, COSV100124432; called by muse, varscan2
- OR4C46 | c.474C>G p.I158M | Missense Mutation (SNP) | VAF 162/688 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.363); catalogued as COSV60219006; called by muse, varscan2
- OR4C6 | c.602G>A p.S201N | Missense Mutation (SNP) | VAF 162/500 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.6); catalogued as COSV58606122; called by muse, mutect2, varscan2
- OR4M1 | c.270G>C p.K90N | Missense Mutation (SNP) | VAF 92/912 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV60061956, COSV60063226; called by muse, mutect2, varscan2
- OR4P4 | c.307C>A p.H103N | Missense Mutation (SNP) | VAF 64/337 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58923029; called by muse, mutect2, varscan2
- OR4Q3 | c.590C>A p.A197D | Missense Mutation (SNP) | VAF 100/1118 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV59179594; called by muse, mutect2
- OR51G1 | c.713G>T p.R238L | Missense Mutation (SNP) | VAF 78/480 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV58969254; called by muse, mutect2, varscan2
- OR52N4 | c.873C>A p.N291K | Missense Mutation (SNP) | VAF 131/523 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199577172; called by muse, mutect2, varscan2
- OR5R1 | c.324G>T p.M108I | Missense Mutation (SNP) | VAF 129/395 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV56571563; called by muse, mutect2, varscan2
- OR5T3 | c.365C>G p.T122R | Missense Mutation (SNP) | VAF 119/465 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57382852; called by muse, mutect2, varscan2
- OR6A2 | c.979G>A p.V327I | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.011); catalogued as rs1400026538; called by muse, mutect2, varscan2
- OR6M1 | c.359G>T p.R120L | Missense Mutation (SNP) | VAF 44/301 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs150034702; called by muse, mutect2, varscan2
- OR9G4 | c.326A>G p.Y109C | Missense Mutation (SNP) | VAF 118/665 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as COSV57249818; called by muse, mutect2, varscan2
- OSBPL6 | c.110A>T p.H37L | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs752567909; called by muse, mutect2, varscan2
- OTOF | c.2359del p.R787Afs*13 (on ENST00000272371 / NM_194248.3; = p.R40Afs*13 on NM_004802.4) | Frame Shift Del (DEL) | VAF 106/561 reads (19%) | catalogued as COSV55511335; called by mutect2, pindel, varscan2
- OTOGL | c.6297C>A p.F2099L (on ENST00000547103; = p.F2090L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV100087075; called by muse, mutect2, varscan2
- PABPC3 | c.1185G>T p.Q395H | Missense Mutation (SNP) | VAF 150/579 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs779009848; called by muse, mutect2, varscan2
- PABPN1 | c.189G>T p.E63D | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs1478129001; called by muse, mutect2, varscan2
- PAOX | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); catalogued as rs756068426; called by muse, mutect2, varscan2
- PAPPA2 | c.1935C>A p.C645* | Nonsense Mutation (SNP) | VAF 32/135 reads (24%) | catalogued as COSV62776173; called by muse, mutect2, varscan2
- PCDH10 | c.1654C>A p.Q552K | Missense Mutation (SNP) | VAF 69/429 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.017); catalogued as COSV52087885; called by muse, mutect2, varscan2
- PCDH17 | c.1190C>A p.T397K | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.051); catalogued as COSV64971497; called by muse, mutect2, varscan2
- PCDH7 | c.2420C>T p.T807M | Missense Mutation (SNP) | VAF 102/384 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752463059; called by muse, mutect2, varscan2
- PCDH8 | c.2956A>G p.T986A | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.217); catalogued as rs201055906; called by muse, mutect2, varscan2
- PCDHA3 | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 43/265 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.301); catalogued as rs533106648; called by muse, mutect2, varscan2
- PCDHB3 | c.1902C>A p.D634E | Missense Mutation (SNP) | VAF 70/310 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.172); catalogued as rs782768757; called by muse, mutect2, varscan2
- PCDHB7 | c.1259C>A p.T420N | Missense Mutation (SNP) | VAF 69/426 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as COSV50759757; called by muse, mutect2, varscan2
- PCDHGA1 | c.2056G>T p.D686Y | Missense Mutation (SNP) | VAF 36/268 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); catalogued as COSV65294883, COSV65295920; called by muse, mutect2, varscan2
- PCDHGA2 | c.2149C>T p.R717W | Missense Mutation (SNP) | VAF 67/465 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.03); catalogued as rs750116599, COSV53892669; called by muse, mutect2, varscan2
- PCDHGA4 | c.2188G>T p.A730S | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.042); catalogued as rs774772455; called by muse, mutect2, varscan2
- PCDHGA6 | c.1235G>T p.R412L | Missense Mutation (SNP) | VAF 113/623 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV53965275; called by muse, mutect2, varscan2
- PCDHGA8 | c.1233C>A p.D411E | Missense Mutation (SNP) | VAF 40/301 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53998374; called by muse, mutect2, varscan2
- PDP1 | c.1264G>T p.E422* | Nonsense Mutation (SNP) | VAF 37/294 reads (13%) | catalogued as COSV99892596; called by muse, mutect2, varscan2
- PGBD2 | c.938A>T p.Q313L | Missense Mutation (SNP) | VAF 63/466 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs770723099; called by muse, mutect2, varscan2
- PHF7 | c.611G>T p.C204F | Missense Mutation (SNP) | VAF 86/583 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59981122; called by muse, mutect2, varscan2
- PIEZO1 | c.919G>T p.G307C | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as rs200651964; called by muse, mutect2, varscan2
- PLPPR4 | c.1723C>T p.R575* | Nonsense Mutation (SNP) | VAF 43/389 reads (11%) | catalogued as COSV64566327; called by muse, mutect2, varscan2
- POTEE | c.2446C>A p.R816S | Missense Mutation (SNP) | VAF 122/726 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as COSV58225008; called by mutect2, varscan2
- PPIC | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs375305758, COSV100120631; called by muse, mutect2, varscan2
- PRDM1 | c.341G>T p.G114V | Missense Mutation (SNP) | VAF 61/261 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64845317; called by muse, mutect2, varscan2
- PROKR1 | c.642G>C p.K214N | Missense Mutation (SNP) | VAF 83/452 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.115); catalogued as COSV58137622; called by muse, mutect2, varscan2
- PTPN14 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 38/198 reads (19%) | catalogued as rs1231768356; called by muse, mutect2, varscan2
- PXDC1 | c.589G>A p.G197S | Missense Mutation (SNP) | VAF 135/264 reads (51%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.013); catalogued as rs966626002; called by muse, mutect2, varscan2
- PXDNL | c.1711G>T p.G571W | Missense Mutation (SNP) | VAF 61/390 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62486819; called by muse, mutect2, varscan2
- PXDNL | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 73/462 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.574); catalogued as COSV62496312; called by muse, mutect2, varscan2
- RARRES1 | c.816G>C p.Q272H | Missense Mutation (SNP) | VAF 67/408 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs1398030805; called by muse, mutect2, varscan2
- RFK | c.49G>A p.G17S | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.682); catalogued as rs775229261; called by muse, mutect2, varscan2
- RFX2 | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as COSV100354038; called by muse, mutect2, varscan2
- RGS1 | c.137+1G>C p.X46_splice | Splice Site (SNP) | VAF 36/155 reads (23%) | catalogued as COSV66504729; called by muse, varscan2
- RGS7 | c.860C>A p.T287K | Missense Mutation (SNP) | VAF 64/549 reads (12%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.844); catalogued as COSV58550062, COSV58557354; called by muse, mutect2, varscan2
- RHBDL1 | c.984G>T p.M328I (on ENST00000219551 / NM_001318733.2; = p.M263I on NM_001278720.2) | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.93); catalogued as COSV99555973; called by muse, mutect2, varscan2
- RNF112 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV71327103; called by muse, mutect2, varscan2
- RNF180 | c.1670G>T p.R557L | Missense Mutation (SNP) | VAF 33/321 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV66635115; called by muse, mutect2, varscan2
- ROBO2 | c.1436G>C p.R479P | Missense Mutation (SNP) | VAF 68/412 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs746150931, COSV100167830, COSV59898161; called by muse, mutect2, varscan2
- ROBO4 | c.2603C>G p.P868R | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs748907210, COSV100127457; called by muse, mutect2, varscan2
- RYR2 | c.13081G>T p.E4361* | Nonsense Mutation (SNP) | VAF 19/77 reads (25%) | catalogued as CM137391, COSV100769920, COSV63683158; called by muse, mutect2, varscan2
- SAFB2 | c.1740G>T p.E580D | Missense Mutation (SNP) | VAF 90/312 reads (29%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); catalogued as CM142579; called by muse, mutect2, varscan2
- SALL3 | c.2447C>A p.T816N | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as COSV73306204; called by muse, mutect2, varscan2
- SAMSN1 | c.295C>T p.H99Y | Missense Mutation (SNP) | VAF 79/330 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs143191486; called by muse, mutect2, varscan2
- SCN10A | c.158C>A p.P53H | Missense Mutation (SNP) | VAF 99/625 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71861480; called by muse, mutect2, varscan2
- SEC23A | c.15G>T p.L5F | Missense Mutation (SNP) | VAF 123/475 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.163); catalogued as COSV56976379; called by muse, mutect2, varscan2
- SERPINE2 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 83/419 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51459360; called by muse, mutect2, varscan2
- SETBP1 | c.1107G>T p.R369S | Missense Mutation (SNP) | VAF 95/633 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.116); catalogued as COSV99953291; called by muse, mutect2, varscan2
- SHOX | c.279G>T p.G93= | Splice Region (SNP) | VAF 56/294 reads (19%) | catalogued as rs193922465; ClinVar: likely benign; called by muse, varscan2
- SHOX | c.356G>T p.R119L | Missense Mutation (SNP) | VAF 61/350 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61861465; called by muse, varscan2
- SHOX2 | c.863C>A p.T288K (on ENST00000441443 / NM_006884.3; = p.T312K on NM_003030.4) | Missense Mutation (SNP) | VAF 46/224 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as rs1441236141; called by muse, mutect2, varscan2
- SLC12A3 | c.2252C>A p.P751Q | Missense Mutation (SNP) | VAF 60/322 reads (19%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.985); catalogued as CM121281; called by muse, mutect2, varscan2
- SLC22A8 | c.973C>A p.R325S | Missense Mutation (SNP) | VAF 52/353 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as COSV60325258; called by muse, mutect2, varscan2
- SLC24A3 | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 117/799 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs996981814, COSV60116161; called by muse, mutect2, varscan2
- SLC44A5 | c.1955C>A p.P652H | Missense Mutation (SNP) | VAF 44/269 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63768191; called by muse, mutect2, varscan2
- SLC7A3 | c.678G>T p.L226F | Missense Mutation (SNP) | VAF 67/142 reads (47%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.873); catalogued as rs757601279, COSV99035693; called by muse, mutect2, varscan2
- SLITRK1 | c.257G>A p.S86N | Missense Mutation (SNP) | VAF 170/622 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.84); catalogued as COSV65676165; called by muse, mutect2, varscan2
- SLITRK2 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 84/182 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374163921, COSV59427100; called by muse, mutect2, varscan2
- SLITRK2 | c.1006G>T p.V336L | Missense Mutation (SNP) | VAF 84/205 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV59422774; called by muse, mutect2, varscan2
- SLITRK6 | c.184C>A p.P62T | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV68389709; called by muse, varscan2
- SLITRK6 | c.154G>T p.G52C | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs867188876, COSV101233245; called by muse, varscan2
- SMG9 | c.1484G>T p.W495L | Missense Mutation (SNP) | VAF 73/295 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as rs1260173173; called by muse, varscan2
- SNTG2 | c.74C>A p.T25K | Missense Mutation (SNP) | VAF 54/240 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as rs757302617, COSV57968142; called by muse, mutect2, varscan2
- SNX31 | c.196G>T p.A66S | Missense Mutation (SNP) | VAF 118/363 reads (33%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.681); catalogued as rs757574415; called by muse, mutect2, varscan2
- SON | c.5206C>T p.P1736S | Missense Mutation (SNP) | VAF 75/288 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.242); catalogued as rs767372328; called by muse, mutect2, varscan2
- SPOCK1 | c.470C>A p.S157Y | Missense Mutation (SNP) | VAF 39/237 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV99969607; called by muse, mutect2, varscan2
- SPTBN1 | c.5445G>T p.K1815N | Missense Mutation (SNP) | VAF 93/447 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.163); catalogued as rs1310554691, COSV61685743; called by muse, mutect2, varscan2
- SRGAP3 | c.3063del p.D1022Mfs*14 | Frame Shift Del (DEL) | VAF 68/400 reads (17%) | catalogued as COSV64530377; called by mutect2, pindel, varscan2
- ST6GALNAC1 | c.1385C>T p.T462M | Missense Mutation (SNP) | VAF 59/328 reads (18%) | PolyPhen probably damaging (0.98); catalogued as rs150096642; called by muse, mutect2, varscan2
- STAB2 | c.6662C>G p.A2221G | Missense Mutation (SNP) | VAF 103/349 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); catalogued as COSV66337116, COSV66339290; called by muse, mutect2, varscan2
- STK11IP | c.382G>T p.G128C | Missense Mutation (SNP) | VAF 88/486 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.974); catalogued as COSV99823184; called by muse, mutect2, varscan2
- STX1B | c.33G>A p.A11= | Splice Region (SNP) | VAF 28/119 reads (24%) | catalogued as rs774354732; ClinVar: likely benign; called by muse, mutect2, varscan2
- TACC3 | c.2244G>T p.K748N | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs530142894; called by muse, mutect2, varscan2
- TAF3 | c.2733G>T p.K911N | Missense Mutation (SNP) | VAF 40/321 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV100720591; called by muse, mutect2, varscan2
- TBC1D24 | c.1393G>A p.A465T (on ENST00000646147 / NM_001199107.2; = p.A459T on NM_020705.3) | Missense Mutation (SNP) | VAF 21/222 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs745535369; called by muse, mutect2
- TECRL | c.435+1G>T p.X145_splice | Splice Site (SNP) | VAF 37/197 reads (19%) | catalogued as COSV101168883; called by muse, mutect2, varscan2
- TGM6 | c.77C>A p.P26H | Missense Mutation (SNP) | VAF 164/533 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.667); catalogued as COSV52481912; called by muse, mutect2, varscan2
- TLR4 | c.1533G>T p.L511F (on ENST00000355622 / NM_138554.5; = p.L471F on NM_003266.4) | Missense Mutation (SNP) | VAF 93/411 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as rs1374466512; called by muse, mutect2, varscan2
- TMEM132E | c.2230G>T p.G744W (on ENST00000321639; = p.G834W on NM_001304438.2) | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.881); catalogued as COSV58699742; called by muse, mutect2, varscan2
- TMPRSS3 | c.655G>T p.G219C | Missense Mutation (SNP) | VAF 81/290 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52302452; called by muse, mutect2, varscan2
- TPO | c.1346C>A p.T449N | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.863); catalogued as COSV61094392; called by muse, mutect2, varscan2
- TRAV26-2 | c.199G>T p.G67C | Missense Mutation (SNP) | VAF 71/447 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1406815549; called by muse, mutect2, varscan2
- TRBV28 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as rs1359596843; called by muse, mutect2, varscan2
- TRIM64C | c.1180C>A p.P394T | Missense Mutation (SNP) | VAF 198/672 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV73267414; called by muse, mutect2, varscan2
- TRPM3 | c.438C>A p.F146L (on ENST00000357533 / NM_001366142.2; = p.F115L on NM_001007471.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/267 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV100624564, COSV100624682; called by muse, mutect2, varscan2
- TTN | c.32926G>C p.A10976P (on ENST00000591111; = p.A10049P on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/414 reads (15%) | PolyPhen benign (0); catalogued as rs765159614; called by muse, mutect2, varscan2
- TTN | c.8388G>T p.K2796N (on ENST00000591111; = p.K2750N on NM_003319.4) | Missense Mutation (SNP) | VAF 100/509 reads (20%) | PolyPhen probably damaging (0.997); catalogued as COSV104415682; called by muse, mutect2, varscan2
- TUBB4A | c.1243A>G p.M415V | Missense Mutation (SNP) | VAF 97/363 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as rs767624506, COSV51155462; called by muse, mutect2, varscan2
- TYW1B | c.350G>C p.R117P | Missense Mutation (SNP) | VAF 78/391 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101444277; called by muse, mutect2, varscan2
- UGT8 | c.430G>T p.G144* | Nonsense Mutation (SNP) | VAF 80/498 reads (16%) | catalogued as COSV60419669; called by muse, mutect2, varscan2
- UGT8 | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 80/501 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60420415; called by muse, mutect2, varscan2
- UNC5D | c.657G>C p.R219S | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV54829305; called by muse, mutect2, varscan2
- USH2A | c.9328C>A p.P3110T | Missense Mutation (SNP) | VAF 67/322 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56398888; called by muse, mutect2, varscan2
- USH2A | c.5579G>T p.G1860V | Missense Mutation (SNP) | VAF 42/384 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56362909; called by muse, mutect2, varscan2
- WASF3 | c.532C>G p.R178G | Missense Mutation (SNP) | VAF 42/319 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); catalogued as COSV58962791; called by muse, mutect2, varscan2
- WNT3A | c.553C>A p.R185S | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as COSV99468802; called by mutect2, varscan2
- XIRP2 | c.8882C>A p.P2961H (on ENST00000628543; = p.P3136H on NM_152381.6) | Missense Mutation (SNP) | VAF 67/323 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV99744204; called by muse, mutect2, varscan2
- ZFHX4 | c.8135G>T p.S2712I | Missense Mutation (SNP) | VAF 36/279 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as rs1176978962; called by muse, mutect2, varscan2
- ZGRF1 | c.173G>T p.G58V | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759660087; called by muse, mutect2, varscan2
- ZIC1 | c.178G>T p.G60C | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs748870052, COSV99291768; called by muse, mutect2, varscan2
- ZNF135 | c.562C>T p.H188Y (on ENST00000313434 / NM_001289401.2; = p.H200Y on NM_003436.4) | Missense Mutation (SNP) | VAF 94/297 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs772730588, COSV57881559; called by muse, mutect2, varscan2
- ZNF208 | c.2597G>A p.C866Y | Missense Mutation (SNP) | VAF 44/275 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV68101577; called by muse, mutect2, varscan2
- ZNF215 | c.854C>A p.P285Q | Missense Mutation (SNP) | VAF 17/194 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as COSV53493976; called by muse, mutect2
- ZNF239 | c.626G>A p.C209Y | Missense Mutation (SNP) | VAF 89/370 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60018011; called by muse, mutect2, varscan2
- ZNF479 | c.728G>T p.C243F | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1369549689; called by muse, mutect2, varscan2
- ZNF675 | c.1679G>T p.G560V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.294); catalogued as COSV100705119; called by muse, mutect2
- ZNF781 | c.703G>T p.G235* | Nonsense Mutation (SNP) | VAF 40/150 reads (27%) | catalogued as COSV62200581; called by muse, mutect2, varscan2
- ZNF85 | c.1565C>A p.S522Y | Missense Mutation (SNP) | VAF 51/177 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV60213329; called by muse, mutect2, varscan2
- ZNF99 | c.1638del p.F546Lfs*8 | Frame Shift Del (DEL) | VAF 36/263 reads (14%) | catalogued as COSV101233976; called by mutect2, pindel, varscan2
- A2ML1 | c.501del p.I168Lfs*14 | Frame Shift Del (DEL) | VAF 133/330 reads (40%) | called by mutect2, pindel, varscan2
- ABCA13 | c.12407T>A p.L4136Q | Missense Mutation (SNP) | VAF 104/267 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ABCB1 | c.898G>C p.G300R | Missense Mutation (SNP) | VAF 119/607 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCB5 | c.1274G>C p.S425T | Missense Mutation (SNP) | VAF 78/584 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- ABCC2 | c.3881G>T p.W1294L | Missense Mutation (SNP) | VAF 81/454 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ABCG4 | c.875T>C p.L292P | Missense Mutation (SNP) | VAF 66/414 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ACACB | c.521C>G p.S174C | Missense Mutation (SNP) | VAF 101/251 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ACTBL2 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 59/301 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- ACTRT2 | c.28C>G p.P10A | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ACTRT2 | c.618C>A p.C206* | Nonsense Mutation (SNP) | VAF 15/86 reads (17%) | called by muse, mutect2, varscan2
- ADAM20 | c.762G>T p.L254F | Missense Mutation (SNP) | VAF 53/198 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ADAM29 | c.1838G>C p.R613T | Missense Mutation (SNP) | VAF 35/268 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ADAM33 | c.1150G>A p.V384M | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- ADAMTS10 | c.113G>C p.S38T | Missense Mutation (SNP) | VAF 80/289 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- ADAMTS7 | c.1270G>T p.A424S | Missense Mutation (SNP) | VAF 60/211 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ADAMTS9 | c.2587G>T p.D863Y | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADAMTS9 | c.1099T>A p.F367I | Missense Mutation (SNP) | VAF 43/358 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTSL1 | c.3309G>T p.Q1103H | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ADAMTSL3 | c.2383T>A p.F795I | Missense Mutation (SNP) | VAF 72/245 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- ADCY2 | c.507C>A p.H169Q | Missense Mutation (SNP) | VAF 54/345 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- ADCY5 | c.1011C>A p.Y337* | Nonsense Mutation (SNP) | VAF 50/291 reads (17%) | called by muse, mutect2, varscan2
- ADGRB3 | c.1183G>T p.A395S | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- ADGRG2 | c.21G>T p.Q7H | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRV1 | c.11119G>T p.V3707L | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ADH1A | c.187C>A p.P63T | Missense Mutation (SNP) | VAF 94/456 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ADRA1A | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 56/340 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADRA1B | c.1135C>A p.R379S | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- AGAP3 | c.1127A>T p.K376M (on ENST00000622464; = p.K412M on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/259 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGBL4 | c.1391G>T p.R464M | Missense Mutation (SNP) | VAF 32/284 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2
- AK5 | c.835A>G p.K279E (on ENST00000354567 / NM_174858.3; = p.K253E on NM_012093.4) | Missense Mutation (SNP) | VAF 38/326 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- AK7 | c.778G>T p.G260* | Nonsense Mutation (SNP) | VAF 74/222 reads (33%) | called by muse, mutect2, varscan2
- AKR1C8P | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 39/307 reads (13%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- ALS2CL | c.816G>T p.K272N | Missense Mutation (SNP) | VAF 69/354 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- ANK2 | c.7592C>A p.S2531* | Nonsense Mutation (SNP) | VAF 67/328 reads (20%) | called by muse, mutect2, varscan2
- ANK3 | c.2842-2A>T p.X948_splice (on ENST00000280772 / NM_001320874.2; = p.X82_splice on NM_001149.3) | Splice Site (SNP) | VAF 25/130 reads (19%) | called by muse, mutect2, varscan2
- ANKRD20A1 | c.124G>T p.V42F | Missense Mutation (SNP) | VAF 57/320 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- ANKRD33B | c.868G>T p.V290L | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKRD63 | c.986G>C p.R329P | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- ANO6 | c.2140G>T p.V714L | Missense Mutation (SNP) | VAF 262/691 reads (38%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- APOB | c.11159C>A p.S3720Y | Missense Mutation (SNP) | VAF 52/255 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ARAP3 | c.3120-1G>A p.X1040_splice | Splice Site (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2
- ARAP3 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP32 | c.172A>T p.R58* | Nonsense Mutation (SNP) | VAF 74/301 reads (25%) | called by muse, mutect2, varscan2
- ARHGAP4 | c.1043T>C p.I348T | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ARHGEF11 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARMC3 | c.703G>T p.D235Y | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ARRDC5 | c.355C>T p.L119F (on ENST00000381781; = p.L105F on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 111/459 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ASXL3 | c.1562G>C p.G521A | Missense Mutation (SNP) | VAF 80/431 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP13A4 | c.1621G>T p.G541W | Missense Mutation (SNP) | VAF 160/690 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BAZ1B | c.2484G>T p.E828D | Missense Mutation (SNP) | VAF 107/628 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- BAZ2A | c.4109C>G p.S1370C | Missense Mutation (SNP) | VAF 119/305 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- BCHE | c.1481C>A p.S494Y | Missense Mutation (SNP) | VAF 92/426 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- BCL11A | c.1381G>C p.E461Q (on ENST00000335712 / NM_001365609.1; = p.E495Q on NM_018014.4) | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- BCL2L1 | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BRDT | c.2389G>C p.D797H | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- BRINP3 | c.889C>A p.Q297K | Missense Mutation (SNP) | VAF 29/280 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- BSX | c.560G>T p.G187V | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C12orf40 | c.1522C>A p.Q508K | Missense Mutation (SNP) | VAF 107/304 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- C16orf82 | c.428C>A p.P143H | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.134); called by muse, mutect2
- C19orf84 | c.367del p.R123Dfs*27 | Frame Shift Del (DEL) | VAF 25/103 reads (24%) | called by mutect2, pindel, varscan2
- C6orf132 | c.1658A>G p.Y553C | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- C7orf33 | c.97del p.R33Gfs*8 | Frame Shift Del (DEL) | VAF 59/423 reads (14%) | called by mutect2, pindel, varscan2
- CACNA2D1 | c.1813A>G p.R605G (on ENST00000356253 / NM_001366867.1; = p.R586G on NM_000722.4) | Missense Mutation (SNP) | VAF 83/363 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- CALCR | c.474G>T p.L158F | Missense Mutation (SNP) | VAF 63/347 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CAMSAP2 | c.3563G>C p.R1188T (on ENST00000236925 / NM_001297707.2; = p.R1177T on NM_203459.3) | Missense Mutation (SNP) | VAF 38/362 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- CARS1 | c.311A>C p.K104T | Missense Mutation (SNP) | VAF 70/244 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- CBLB | c.1156G>T p.E386* | Nonsense Mutation (SNP) | VAF 119/575 reads (21%) | called by muse, mutect2, varscan2
- CCDC151 | c.1754del p.S585Ifs*42 | Frame Shift Del (DEL) | VAF 62/286 reads (22%) | called by mutect2, pindel*, varscan2
- CCDC186 | c.719G>T p.R240I | Missense Mutation (SNP) | VAF 98/407 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC57 | c.1395G>T p.E465D | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CCDC73 | c.2557G>T p.V853F | Missense Mutation (SNP) | VAF 77/269 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- CCDC80 | c.1537A>T p.S513C | Missense Mutation (SNP) | VAF 115/490 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- CCNE1 | c.854G>T p.C285F | Missense Mutation (SNP) | VAF 83/293 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCT6A | c.847G>C p.G283R | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- CD163L1 | c.2624C>A p.P875H | Missense Mutation (SNP) | VAF 196/430 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- CD226 | c.764G>T p.G255V | Missense Mutation (SNP) | VAF 46/427 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CD226 | c.170A>T p.Q57L | Missense Mutation (SNP) | VAF 115/735 reads (16%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD46 | c.419A>T p.Y140F | Missense Mutation (SNP) | VAF 57/370 reads (15%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CD5 | c.193G>T p.G65C | Missense Mutation (SNP) | VAF 79/403 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- CD81 | c.324del p.G109Afs*15 | Frame Shift Del (DEL) | VAF 91/553 reads (16%) | called by mutect2, pindel, varscan2
- CDH7 | c.2171C>A p.A724D | Missense Mutation (SNP) | VAF 114/637 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDRT1 | c.1996C>T p.Q666* | Nonsense Mutation (SNP) | VAF 92/420 reads (22%) | called by muse, mutect2, varscan2
- CELA3B | c.268C>G p.R90G | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- CEP350 | c.5252A>T p.Q1751L | Missense Mutation (SNP) | VAF 38/349 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CERS1 | c.637G>T p.D213Y | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CFAP46 | c.2678C>A p.T893N | Missense Mutation (SNP) | VAF 72/212 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CHRND | c.1186C>A p.R396S | Missense Mutation (SNP) | VAF 57/414 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLDN17 | c.541C>A p.L181M | Missense Mutation (SNP) | VAF 93/608 reads (15%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- CLGN | c.1763C>A p.A588E | Missense Mutation (SNP) | VAF 35/302 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- CNGB3 | c.775A>T p.I259L | Missense Mutation (SNP) | VAF 304/806 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CNTN5 | c.2710G>C p.G904R | Missense Mutation (SNP) | VAF 55/283 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL11A1 | c.2719G>T p.G907C | Missense Mutation (SNP) | VAF 107/550 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL20A1 | c.2170G>T p.G724W | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A2 | c.472C>A p.P158T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- COL5A2 | c.2134G>A p.E712K | Missense Mutation (SNP) | VAF 93/483 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- COL6A5 | c.2590A>G p.I864V | Missense Mutation (SNP) | VAF 132/540 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- COLEC12 | c.2198A>G p.D733G | Missense Mutation (SNP) | VAF 64/260 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- COPA | c.1394T>A p.L465Q | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CPED1 | c.1137A>G p.V379= | Splice Region (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2, varscan2
- CR2 | c.1376G>T p.W459L | Missense Mutation (SNP) | VAF 98/492 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTBP1 | c.762+1G>C p.X254_splice | Splice Site (SNP) | VAF 8/201 reads (4%) | called by muse, mutect2
- CTNNA3 | c.1903G>T p.D635Y | Missense Mutation (SNP) | VAF 52/537 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- CTSG | c.430G>C p.V144L | Missense Mutation (SNP) | VAF 106/460 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- CUL9 | c.863G>T p.C288F | Missense Mutation (SNP) | VAF 63/291 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CUX1 | c.4172A>T p.H1391L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYLC1 | c.1307C>A p.S436Y | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- CYP27C1 | c.721C>A p.L241M | Missense Mutation (SNP) | VAF 69/307 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- CYP2E1 | c.380G>T p.R127L | Missense Mutation (SNP) | VAF 81/242 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- D2HGDH | c.276G>T p.W92C | Missense Mutation (SNP) | VAF 39/219 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DAGLA | c.37G>T p.V13L | Missense Mutation (SNP) | VAF 101/420 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- DDIAS | c.2336G>T p.G779V | Missense Mutation (SNP) | VAF 49/347 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- DDX52 | c.1193G>T p.G398V | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DDX52 | c.218A>T p.K73I | Missense Mutation (SNP) | VAF 113/578 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- DGKH | c.1591G>T p.D531Y | Missense Mutation (SNP) | VAF 53/361 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- DGKI | c.1225C>A p.L409I | Missense Mutation (SNP) | VAF 45/257 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DGKQ | c.2292G>T p.E764D | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- DHODH | c.10A>G p.R4G | Missense Mutation (SNP) | VAF 34/392 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2
- DIPK1C | c.411G>T p.E137D | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- DIS3 | c.1279G>T p.E427* | Nonsense Mutation (SNP) | VAF 53/204 reads (26%) | called by muse, mutect2, varscan2
- DISC1 | c.2163G>T p.Q721H | Missense Mutation (SNP) | VAF 38/233 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- DNAH17 | c.6569T>A p.L2190Q | Missense Mutation (SNP) | VAF 66/288 reads (23%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DNER | c.1724G>T p.G575V | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNHD1 | c.7183T>A p.S2395T | Missense Mutation (SNP) | VAF 221/645 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- DNMT3L | c.597C>G p.I199M | Missense Mutation (SNP) | VAF 67/287 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DOCK2 | c.2753C>A p.T918K | Missense Mutation (SNP) | VAF 60/408 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- DPH5 | c.118G>T p.V40L | Missense Mutation (SNP) | VAF 66/295 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- DRD3 | c.140dup p.N47Kfs*58 | Frame Shift Ins (INS) | VAF 50/223 reads (22%) | called by mutect2, pindel, varscan2
- DST | c.3244T>A p.C1082S (on ENST00000361203 / NM_001374722.1; = p.C756S on NM_001723.6) | Missense Mutation (SNP) | VAF 55/263 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- DYNC1I1 | c.1838C>A p.P613H | Missense Mutation (SNP) | VAF 66/295 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- EDRF1 | c.1504G>T p.A502S (on ENST00000356792 / NM_001202438.2; = p.A468S on NM_015608.2) | Missense Mutation (SNP) | VAF 53/230 reads (23%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EHMT2 | c.3174C>G p.I1058M | Missense Mutation (SNP) | VAF 145/274 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- EIF4G1 | c.182G>T p.S61I | Missense Mutation (SNP) | VAF 73/301 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ELOA2 | c.1022C>A p.S341Y | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- ELP6 | c.609G>T p.Q203H | Missense Mutation (SNP) | VAF 90/362 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.259); called by mutect2, varscan2
- EPHB6 | c.882G>T p.M294I | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- ERVV-1 | c.1187G>T p.G396V | Missense Mutation (SNP) | VAF 82/231 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ESRRB | c.809G>T p.G270V | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- EXO1 | c.2197C>A p.P733T | Missense Mutation (SNP) | VAF 34/332 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- EXO5 | c.39A>T p.E13D | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- EYS | c.3763C>A p.P1255T | Missense Mutation (SNP) | VAF 59/187 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, varscan2
- F7 | c.754G>T p.A252S | Missense Mutation (SNP) | VAF 58/274 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM135B | c.2995A>G p.K999E | Missense Mutation (SNP) | VAF 145/322 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM216B | c.320G>T p.R107L | Missense Mutation (SNP) | VAF 84/327 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- FANCG | c.1629G>T p.M543I | Missense Mutation (SNP) | VAF 20/622 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FASLG | c.211C>A p.L71M | Missense Mutation (SNP) | VAF 53/370 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FASLG | c.478_479insA p.L160Hfs*18 | Frame Shift Ins (INS) | VAF 44/217 reads (20%) | called by mutect2, pindel*, varscan2
- FAT2 | c.10357_10358del p.P3453Rfs*34 | Frame Shift Del (DEL) | VAF 51/449 reads (11%) | called by mutect2, pindel, varscan2
- FAT3 | c.12278T>G p.V4093G | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- FAT3 | c.12559A>C p.N4187H | Missense Mutation (SNP) | VAF 170/560 reads (30%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FAT4 | c.10450G>T p.A3484S | Missense Mutation (SNP) | VAF 81/467 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FBRSL1 | c.350_351insT p.K117Nfs*16 | Frame Shift Ins (INS) | VAF 126/489 reads (26%) | called by mutect2, pindel*, varscan2
- FBXO15 | c.854G>T p.C285F | Missense Mutation (SNP) | VAF 64/366 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- FBXO40 | c.689C>A p.A230D | Missense Mutation (SNP) | VAF 67/250 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.054); called by muse, varscan2
- FCGBP | c.8330G>A p.G2777D | Missense Mutation (SNP) | VAF 118/488 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.02); called by muse, varscan2
- FGD5 | c.730C>G p.Q244E | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLII | c.2318G>T p.R773L | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- FLNA | c.4597A>G p.S1533G | Missense Mutation (SNP) | VAF 141/326 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- FLOT1 | c.73G>C p.A25P | Missense Mutation (SNP) | VAF 132/296 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- FLT3 | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 60/393 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.455); called by muse, mutect2
- FMN2 | c.3599C>T p.P1200L | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- FNDC3B | c.710G>T p.G237V | Missense Mutation (SNP) | VAF 107/375 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- FOXG1 | c.1470A>T p.*490Yext*21 | Nonstop Mutation (SNP) | VAF 107/765 reads (14%) | called by muse, mutect2, varscan2
- FOXP2 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 196/766 reads (26%) | called by muse, varscan2
- FREM3 | c.4034T>G p.V1345G | Missense Mutation (SNP) | VAF 51/260 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- FRG2 | c.691del p.A231Qfs*36 | Frame Shift Del (DEL) | VAF 12/57 reads (21%) | called by mutect2, varscan2
- GAK | c.3736G>T p.E1246* | Nonsense Mutation (SNP) | VAF 36/131 reads (27%) | called by muse, mutect2, varscan2
- GASK1B | c.754G>T p.G252C | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- GASK1B | c.499G>T p.A167S | Missense Mutation (SNP) | VAF 47/250 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- GCGR | c.1381G>T p.A461S | Missense Mutation (SNP) | VAF 39/232 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GFI1 | c.674G>T p.R225L | Missense Mutation (SNP) | VAF 70/292 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- GHR | c.1805A>T p.Q602L | Missense Mutation (SNP) | VAF 98/446 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- GIN1 | c.974A>T p.K325I | Missense Mutation (SNP) | VAF 51/349 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- GLB1L3 | c.1340G>T p.G447V | Missense Mutation (SNP) | VAF 65/324 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- GLI2 | c.701C>A p.S234Y | Missense Mutation (SNP) | VAF 96/507 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- GLRA3 | c.368T>A p.L123* | Nonsense Mutation (SNP) | VAF 58/337 reads (17%) | called by muse, mutect2, varscan2
- GNA12 | c.776A>G p.Q259R | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- GPR87 | c.926T>A p.L309Q | Missense Mutation (SNP) | VAF 74/362 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPRC5C | c.1303A>T p.I435F (on ENST00000652232; = p.I390F on NM_018653.4) | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- GRAMD2B | c.383-1G>T p.X128_splice | Splice Site (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- GRIA4 | c.250T>A p.C84S | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIK4 | c.2830C>A p.L944M | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- GRIN2B | c.3956C>A p.P1319Q | Missense Mutation (SNP) | VAF 140/277 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- H3C2 | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 88/196 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- HDAC9 | c.214C>T p.H72Y | Missense Mutation (SNP) | VAF 271/760 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HECTD4 | c.8584G>T p.A2862S | Missense Mutation (SNP) | VAF 79/162 reads (49%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HID1 | c.478G>T p.V160F | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- HMCN1 | c.5579G>T p.W1860L | Missense Mutation (SNP) | VAF 38/380 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HMCN2 | c.5927G>T p.R1976L | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.79); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HMCN2 | c.10462G>T p.G3488W | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOXA4 | c.616+5G>A | Splice Region (SNP) | VAF 91/365 reads (25%) | called by muse, mutect2, varscan2
- HOXA7 | c.460T>A p.Y154N | Missense Mutation (SNP) | VAF 98/354 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSD11B2 | c.224C>A p.P75Q | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HSPA12B | c.1331G>T p.G444V | Missense Mutation (SNP) | VAF 89/535 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HTR3D | c.457G>T p.G153W (on ENST00000382489 / NM_001163646.2; = p.G18W on NM_182537.3) | Missense Mutation (SNP) | VAF 101/483 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- HTR5A | c.814G>T p.G272W | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- HUS1 | c.457G>C p.D153H | Missense Mutation (SNP) | VAF 98/360 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- IGFBPL1 | c.121T>C p.C41R | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- IGKV3D-20 | c.14C>A p.A5E | Missense Mutation (SNP) | VAF 51/320 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- IK | c.1439G>T p.R480L | Missense Mutation (SNP) | VAF 37/339 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- IKZF1 | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 237/1170 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IL31RA | c.216C>A p.C72* | Nonsense Mutation (SNP) | VAF 64/564 reads (11%) | called by muse, mutect2, varscan2
- IL7R | c.1025G>T p.G342V | Missense Mutation (SNP) | VAF 100/531 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ING5 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- INSYN2B | c.80C>A p.P27H | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- INTS6 | c.1443G>T p.E481D | Missense Mutation (SNP) | VAF 69/296 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- IPO7 | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 89/383 reads (23%) | called by muse, mutect2, varscan2
- IQCA1 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 33/267 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- IQGAP2 | c.934G>T p.A312S | Missense Mutation (SNP) | VAF 31/266 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ITGA10 | c.1630C>T p.P544S | Missense Mutation (SNP) | VAF 63/334 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ITGAD | c.3229C>A p.L1077I | Missense Mutation (SNP) | VAF 136/544 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.075); called by muse, varscan2
- ITGAX | c.682A>T p.T228S | Missense Mutation (SNP) | VAF 34/259 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IYD | c.156_178+13del p.X52_splice | Splice Site (DEL) | VAF 38/194 reads (20%) | called by mutect2, pindel
- JAKMIP1 | c.937G>T p.D313Y | Missense Mutation (SNP) | VAF 65/271 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- KAT6A | c.4126G>C p.E1376Q | Missense Mutation (SNP) | VAF 70/243 reads (29%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- KATNIP | c.2324G>T p.W775L | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- KCNB2 | c.2470G>T p.E824* | Nonsense Mutation (SNP) | VAF 70/337 reads (21%) | called by muse, mutect2, varscan2
- KCNH5 | c.1363G>T p.V455F | Missense Mutation (SNP) | VAF 75/269 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- KCNK6 | c.33G>T p.L11F | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- KCNMB3 | c.274_276del p.E92del | In Frame Del (DEL) | VAF 110/584 reads (19%) | called by pindel, varscan2
- KCNT2 | c.1069G>T p.V357F | Missense Mutation (SNP) | VAF 38/375 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KCTD16 | c.383A>G p.K128R | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- KCTD8 | c.1306G>T p.V436L | Missense Mutation (SNP) | VAF 75/401 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KDM4E | c.1207C>G p.P403A | Missense Mutation (SNP) | VAF 71/390 reads (18%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- KEL | c.555G>T p.W185C | Missense Mutation (SNP) | VAF 111/578 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KERA | c.626C>A p.P209Q | Missense Mutation (SNP) | VAF 122/374 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- KIAA0513 | c.1039G>C p.E347Q | Missense Mutation (SNP) | VAF 61/225 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- KIAA1614 | c.654dup p.G219Rfs*10 | Frame Shift Ins (INS) | VAF 26/123 reads (21%) | called by mutect2, pindel, varscan2
- KIAA1755 | c.1968T>C p.A656= | Splice Region (SNP) | VAF 44/195 reads (23%) | called by muse, mutect2, varscan2
- KIF21B | c.3602G>T p.R1201L | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIF26B | c.793G>T p.G265C | Missense Mutation (SNP) | VAF 78/307 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- KIR3DL1 | c.947C>A p.T316K | Missense Mutation (SNP) | VAF 74/326 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.115); called by muse, varscan2
- KIT | c.2029G>T p.D677Y | Missense Mutation (SNP) | VAF 48/358 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KMT2E | c.498G>T p.R166S | Missense Mutation (SNP) | VAF 48/303 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KRT77 | c.218A>G p.N73S | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRTAP15-1 | c.343C>A p.L115M | Missense Mutation (SNP) | VAF 55/243 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- KRTAP4-11 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 66/504 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, varscan2
- L1CAM | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 121/278 reads (44%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- LAMA5 | c.4953G>T p.E1651D | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAMC3 | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 95/298 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- LARS1 | c.688A>G p.K230E (on ENST00000394434 / NM_020117.11; = p.K203E on NM_016460.3) | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- LCP2 | c.1107C>A p.S369R | Missense Mutation (SNP) | VAF 46/421 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LEPR | c.1341C>A p.C447* | Nonsense Mutation (SNP) | VAF 39/382 reads (10%) | called by muse, mutect2, varscan2
- LGALS1 | c.287A>C p.N96T | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- LHFPL6 | c.95G>T p.W32L | Missense Mutation (SNP) | VAF 36/264 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LILRB2 | c.4A>T p.T2S | Missense Mutation (SNP) | VAF 52/249 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- LIN28A | c.487T>A p.F163I | Missense Mutation (SNP) | VAF 69/481 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- LINC02860 | n.890C>A | Splice Region (SNP) | VAF 91/372 reads (24%) | called by muse, mutect2, varscan2
- LMO7 | c.2954A>G p.Q985R (on ENST00000357063; = p.Q666R on NM_005358.5) | Missense Mutation (SNP) | VAF 150/632 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LNP1 | c.63G>T p.W21C | Missense Mutation (SNP) | VAF 96/481 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LPO | c.1181C>A p.A394D | Missense Mutation (SNP) | VAF 59/299 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LRFN2 | c.1976C>A p.A659D | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LRIF1 | c.796A>T p.T266S | Missense Mutation (SNP) | VAF 64/301 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- LRP1B | c.3269G>A p.G1090D | Missense Mutation (SNP) | VAF 55/317 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- LRP2 | c.12547G>T p.D4183Y | Missense Mutation (SNP) | VAF 58/465 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- LRRC15 | c.785C>A p.P262H | Missense Mutation (SNP) | VAF 132/517 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- LRRC7 | c.1975C>A p.P659T (on ENST00000651989 / NM_001370785.2; = p.P626T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/245 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- LRRC7 | c.2743C>G p.H915D (on ENST00000651989 / NM_001370785.2; = p.H882D on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/490 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2
- LRRTM3 | c.1735C>A p.Q579K | Missense Mutation (SNP) | VAF 83/322 reads (26%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRTM1 | c.161C>A p.T54K | Missense Mutation (SNP) | VAF 78/423 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- LSP1 | c.64C>T p.Q22* | Nonsense Mutation (SNP) | VAF 15/126 reads (12%) | called by muse, mutect2, varscan2
- LTBP1 | c.1756G>A p.G586S (on ENST00000404816 / NM_206943.4; = p.G260S on NM_000627.4) | Missense Mutation (SNP) | VAF 73/399 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LTBP4 | c.3243G>T p.E1081D (on ENST00000308370 / NM_001042544.1; = p.E1044D on NM_003573.2) | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MACF1 | c.390G>T p.R130S | Missense Mutation (SNP) | VAF 80/392 reads (20%) | called by muse, mutect2, varscan2
- MACF1 | c.16786del p.E5596Nfs*13 (on ENST00000372915; = p.E3638Nfs*13 on NM_012090.5) | Frame Shift Del (DEL) | VAF 47/322 reads (15%) | called by mutect2, pindel, varscan2
- MACROD2 | c.215T>C p.V72A | Missense Mutation (SNP) | VAF 76/225 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.291); called by muse, varscan2
- MAGEA4 | c.597del p.T200Qfs*4 | Frame Shift Del (DEL) | VAF 33/92 reads (36%) | called by mutect2, pindel, varscan2
- MAML3 | c.1844G>T p.R615M | Missense Mutation (SNP) | VAF 139/570 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- MAP3K1 | c.1861G>T p.G621W | Missense Mutation (SNP) | VAF 64/396 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MAP3K14 | c.616G>T p.G206W | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- MAP3K19 | c.1469C>T p.P490L | Missense Mutation (SNP) | VAF 71/398 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- MAP3K6 | c.2101del p.R701Afs*5 | Frame Shift Del (DEL) | VAF 21/186 reads (11%) | called by mutect2, pindel, varscan2
- MAP3K8 | c.1138G>T p.A380S | Missense Mutation (SNP) | VAF 174/739 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MAPK8 | c.349del p.Q117Kfs*2 | Frame Shift Del (DEL) | VAF 5/43 reads (12%) | called by mutect2, pindel, varscan2
- MATN2 | c.996A>T p.E332D | Missense Mutation (SNP) | VAF 61/532 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- MC2R | c.695G>T p.W232L | Missense Mutation (SNP) | VAF 126/548 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MCAT | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCC | c.171G>A p.Q57= | Splice Region (SNP) | VAF 38/205 reads (19%) | called by muse, mutect2, varscan2
- MDGA1 | c.2628G>T p.Q876H | Missense Mutation (SNP) | VAF 52/306 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- MDGA2 | c.181del p.A61Lfs*8 | Frame Shift Del (DEL) | VAF 118/386 reads (31%) | called by mutect2, pindel, varscan2
- MED13 | c.466A>G p.K156E | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MFF | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 111/561 reads (20%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MGA | c.7494_7498delinsG p.V2499Rfs*12 (on ENST00000219905 / NM_001164273.1; = p.V2290Rfs*12 on NM_001080541.2) | Frame Shift Del (DEL) | VAF 28/112 reads (25%) | called by pindel, varscan2*
- MICU3 | c.697C>G p.P233A | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MMP16 | c.480G>T p.Q160H | Missense Mutation (SNP) | VAF 101/258 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- MMP27 | c.1114C>A p.R372S | Missense Mutation (SNP) | VAF 65/282 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- MOGS | c.2069G>T p.G690V | Missense Mutation (SNP) | VAF 73/324 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MPP7 | c.873G>T p.K291N | Missense Mutation (SNP) | VAF 33/184 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.411); called by muse, mutect2
- MRC1 | c.3991G>T p.D1331Y | Missense Mutation (SNP) | VAF 101/746 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- MRGPRG | c.759G>T p.L253F | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MRPL11 | c.217A>T p.K73* | Nonsense Mutation (SNP) | VAF 71/243 reads (29%) | called by muse, mutect2, varscan2
- MRPL11 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MS4A18 | c.473C>A p.A158D (on ENST00000398983; = p.A160D on NM_001354471.1) | Missense Mutation (SNP) | VAF 70/340 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- MUC12 | c.8093C>T p.P2698L (on ENST00000379442; = p.P2555L on NM_001164462.1) | Missense Mutation (SNP) | VAF 294/812 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- MUC12 | c.11069C>T p.S3690L (on ENST00000379442; = p.S3547L on NM_001164462.1) | Missense Mutation (SNP) | VAF 300/1147 reads (26%) | SIFT deleterious (0.02); called by muse, mutect2, varscan2
- MUC22 | c.119C>A p.A40D | Missense Mutation (SNP) | VAF 56/102 reads (55%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2
- MVB12A | c.680A>T p.E227V | Missense Mutation (SNP) | VAF 79/257 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- MYH4 | c.3943C>A p.Q1315K | Missense Mutation (SNP) | VAF 64/256 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- MYH7 | c.2750C>A p.A917D | Missense Mutation (SNP) | VAF 64/346 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- MYH7 | c.1991C>A p.S664Y | Missense Mutation (SNP) | VAF 152/821 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- MYLK2 | c.-48C>G | Splice Region (SNP) | VAF 98/442 reads (22%) | called by muse, mutect2, varscan2
- NAF1 | c.298G>T p.G100* | Nonsense Mutation (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- NALCN | c.4366A>T p.T1456S | Missense Mutation (SNP) | VAF 53/307 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NBAS | c.1859A>T p.K620I | Missense Mutation (SNP) | VAF 64/510 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- NBEAL1 | c.2678C>T p.P893L | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- NDST4 | c.1788dup p.F597Ifs*30 | Frame Shift Ins (INS) | VAF 24/144 reads (17%) | called by pindel, varscan2
- NDST4 | c.1783C>A p.P595T | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- NELL2 | c.928A>T p.N310Y | Missense Mutation (SNP) | VAF 153/383 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- NETO1 | c.376A>G p.I126V | Missense Mutation (SNP) | VAF 57/252 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- NEXMIF | c.222G>T p.M74I | Missense Mutation (SNP) | VAF 76/213 reads (36%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRC3 | c.3058A>T p.I1020L | Missense Mutation (SNP) | VAF 34/262 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- NLRP3 | c.1537G>C p.E513Q | Missense Mutation (SNP) | VAF 55/370 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- NMS | c.206G>T p.R69M | Missense Mutation (SNP) | VAF 46/284 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NRROS | c.112G>T p.G38C | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.43); called by muse, mutect2
- NRROS | c.444G>T p.M148I | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- NRXN1 | c.2117G>T p.G706V | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); called by muse, varscan2
- NRXN2 | c.4160A>T p.D1387V | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, mutect2
- NT5DC2 | c.382-5C>A | Splice Region (SNP) | VAF 20/93 reads (22%) | called by muse, mutect2, varscan2
- NYAP1 | c.280G>T p.V94F | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- NYAP2 | c.335G>T p.S112I | Missense Mutation (SNP) | VAF 50/269 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- ODF3 | c.676-5C>A | Splice Region (SNP) | VAF 63/223 reads (28%) | called by muse, mutect2, varscan2
- OLAH | c.550C>A p.L184M (on ENST00000378228 / NM_001039702.3; = p.L237M on NM_018324.3) | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- OPRPN | c.635C>A p.P212H | Missense Mutation (SNP) | VAF 37/240 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- OR10A4 | c.286C>T p.L96F | Missense Mutation (SNP) | VAF 46/456 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.063); called by muse, mutect2
- OR10G4 | c.179T>A p.F60Y | Missense Mutation (SNP) | VAF 91/368 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, varscan2
- OR11H12 | c.204G>T p.W68C | Missense Mutation (SNP) | VAF 90/284 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0); called by mutect2, varscan2
- OR2L13 | c.506G>T p.R169M | Missense Mutation (SNP) | VAF 62/262 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- OR2L5 | c.157C>A p.H53N | Missense Mutation (SNP) | VAF 63/511 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OR2L5 | c.388C>A p.H130N | Missense Mutation (SNP) | VAF 126/552 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- OR4Q2 | c.187C>A p.L63I | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR4Q3 | c.592T>C p.C198R | Missense Mutation (SNP) | VAF 100/1146 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR51B4 | c.375dup p.P126Tfs*63 | Frame Shift Ins (INS) | VAF 64/443 reads (14%) | called by mutect2, pindel, varscan2
- OR52K1 | c.628G>T p.V210L | Missense Mutation (SNP) | VAF 45/527 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.036); called by muse, mutect2
- OR56A3 | c.799G>A p.V267M | Missense Mutation (SNP) | VAF 117/421 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- OR6S1 | c.643C>G p.L215V | Missense Mutation (SNP) | VAF 74/312 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OR8A1 | c.852G>T p.L284F | Missense Mutation (SNP) | VAF 108/322 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- OR8B2 | c.725G>T p.S242I | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OTOF | c.3895-2A>T p.X1299_splice (on ENST00000272371 / NM_194248.3; = p.X532_splice on NM_004802.4) | Splice Site (SNP) | VAF 108/476 reads (23%) | called by muse, varscan2
- OTOF | c.3448C>A p.L1150M (on ENST00000272371 / NM_194248.3; = p.L403M on NM_004802.4) | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- OTOGL | c.6995C>A p.S2332* (on ENST00000547103; = p.S2323* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 80/244 reads (33%) | called by muse, mutect2, varscan2
- PACS1 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 127/444 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PAPOLG | c.1103A>G p.Q368R | Missense Mutation (SNP) | VAF 82/376 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- PAPPA2 | c.1710C>A p.H570Q | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.043); called by muse, mutect2
- PAPSS1 | c.478G>T p.A160S | Missense Mutation (SNP) | VAF 48/313 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PARD3 | c.3773G>T p.R1258M | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PAX5 | c.275C>A p.T92K | Missense Mutation (SNP) | VAF 30/458 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- PAXIP1 | c.748G>T p.D250Y | Missense Mutation (SNP) | VAF 158/727 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PC | c.50G>T p.R17L | Missense Mutation (SNP) | VAF 83/412 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCBP3 | c.941C>A p.T314N | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- PCDH15 | c.3829G>T p.E1277* | Nonsense Mutation (SNP) | VAF 111/450 reads (25%) | called by muse, mutect2, varscan2
- PCDH18 | c.344C>A p.T115K | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCDH7 | c.3112T>A p.S1038T | Missense Mutation (SNP) | VAF 89/378 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHA1 | c.919A>T p.K307* | Nonsense Mutation (SNP) | VAF 24/149 reads (16%) | called by muse, mutect2, varscan2
- PCDHA13 | c.719C>A p.P240Q | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHA4 | c.176T>A p.L59Q | Missense Mutation (SNP) | VAF 68/314 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCDHB11 | c.1712C>G p.P571R | Missense Mutation (SNP) | VAF 33/479 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- PCDHB6 | c.1783G>T p.G595C | Missense Mutation (SNP) | VAF 43/365 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PCDHB7 | c.2256C>G p.C752W | Missense Mutation (SNP) | VAF 39/232 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PCM1 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 51/350 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCSK7 | c.864G>T p.W288C | Missense Mutation (SNP) | VAF 76/280 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDE7A | c.773G>A p.G258D (on ENST00000401827 / NM_001242318.3; = p.G232D on NM_002603.4) | Missense Mutation (SNP) | VAF 14/308 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PDE7B | c.1079G>T p.S360I | Missense Mutation (SNP) | VAF 72/253 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDGFRA | c.1504C>A p.L502M | Missense Mutation (SNP) | VAF 88/415 reads (21%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- PDLIM5 | c.62G>A p.G21D | Missense Mutation (SNP) | VAF 71/457 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PDZRN3 | c.2991G>T p.Q997H | Missense Mutation (SNP) | VAF 57/290 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PHLDB2 | c.3465del p.I1157Lfs*29 (on ENST00000393925 / NM_001134439.2; = p.I1114Lfs*29 on NM_145753.2) | Frame Shift Del (DEL) | VAF 133/678 reads (20%) | called by mutect2, pindel, varscan2
- PIBF1 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 37/221 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PIK3R1 | c.1523A>T p.Y508F (on ENST00000521381 / NM_181523.3; = p.Y238F on NM_181504.4) | Missense Mutation (SNP) | VAF 30/211 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- PKD2L1 | c.586G>T p.G196W | Missense Mutation (SNP) | VAF 83/637 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLA2G1B | c.208C>G p.H70D | Missense Mutation (SNP) | VAF 195/396 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLD5 | c.1014G>T p.Q338H (on ENST00000442594; = p.Q276H on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/303 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLXNB2 | c.553A>C p.T185P | Missense Mutation (SNP) | VAF 80/259 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- PNLIPRP1 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 64/212 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- POSTN | c.607-1G>T p.X203_splice | Splice Site (SNP) | VAF 79/358 reads (22%) | called by muse, mutect2, varscan2
- POSTN | c.606+2T>A p.X202_splice | Splice Site (SNP) | VAF 26/94 reads (28%) | called by muse, mutect2
- POT1 | c.1103C>A p.S368* | Nonsense Mutation (SNP) | VAF 41/206 reads (20%) | called by muse, mutect2, varscan2
- POTEE | c.814G>T p.G272C | Missense Mutation (SNP) | VAF 40/405 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- POTEF | c.814G>T p.G272C | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); called by muse, varscan2
- PPP1R3A | c.604G>T p.G202C | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRDM4 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 57/212 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PRDM9 | c.2253G>T p.R751S | Missense Mutation (SNP) | VAF 80/548 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.161); called by muse, varscan2
- PREX2 | c.3148del p.L1050Ffs*5 | Frame Shift Del (DEL) | VAF 8/82 reads (10%) | called by mutect2, varscan2
- PRKAB2 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 47/205 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRKCB | c.1358G>C p.G453A | Missense Mutation (SNP) | VAF 46/249 reads (18%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- PRKDC | c.12271G>T p.A4091S | Missense Mutation (SNP) | VAF 81/445 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- PRND | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 96/578 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PROM1 | c.2583-3del | Splice Region (DEL) | VAF 24/162 reads (15%) | called by pindel, varscan2
- PROM2 | c.1150G>T p.V384L | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PRSS58 | c.23C>G p.A8G | Missense Mutation (SNP) | VAF 78/409 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, varscan2
- PSME4 | c.445G>T p.V149L | Missense Mutation (SNP) | VAF 60/336 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTGIS | c.511T>A p.F171I | Missense Mutation (SNP) | VAF 49/199 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PTPN13 | c.6969G>T p.W2323C (on ENST00000411767 / NM_080683.3; = p.W2304C on NM_006264.3) | Missense Mutation (SNP) | VAF 65/447 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRA | c.538T>C p.Y180H | Missense Mutation (SNP) | VAF 114/694 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PTPRD | c.2686T>A p.S896T | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.314); called by muse, mutect2
- PTPRJ | c.2549A>G p.Y850C | Missense Mutation (SNP) | VAF 102/386 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PTPRQ | c.4009G>T p.G1337* (on ENST00000616559; = p.G1295* on NM_001145026.2) | Nonsense Mutation (SNP) | VAF 38/327 reads (12%) | called by muse, mutect2, varscan2
- PTPRQ | c.4010G>T p.G1337V (on ENST00000616559; = p.G1295V on NM_001145026.2) | Missense Mutation (SNP) | VAF 38/326 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- QSER1 | c.3155G>T p.G1052V (on ENST00000399302; = p.G1181V on NM_001076786.3) | Missense Mutation (SNP) | VAF 106/414 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- RAB3GAP2 | c.1785G>C p.L595F | Missense Mutation (SNP) | VAF 32/332 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2
- RAD51AP2 | c.2295G>T p.M765I | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAD54L2 | c.3090del p.I1031Sfs*3 | Frame Shift Del (DEL) | VAF 32/183 reads (17%) | called by mutect2, pindel, varscan2
- RAG1 | c.2495G>T p.W832L | Missense Mutation (SNP) | VAF 242/965 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RAP1GDS1 | c.366G>T p.E122D (on ENST00000408927 / NM_001100427.2; = p.E123D on NM_021159.5) | Missense Mutation (SNP) | VAF 62/355 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- RASAL3 | c.1691A>T p.E564V | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- RBBP8NL | c.1969A>T p.N657Y | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- RBM14 | c.1820G>T p.R607L | Missense Mutation (SNP) | VAF 53/239 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- RBP3 | c.2113C>A p.P705T | Missense Mutation (SNP) | VAF 57/192 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- RFC3 | c.898A>T p.R300* | Nonsense Mutation (SNP) | VAF 37/310 reads (12%) | called by muse, mutect2, varscan2
- RFPL4A | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 121/792 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RFPL4AL1 | c.275G>C p.R92T | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.65); called by mutect2, varscan2
- RFTN2 | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 128/582 reads (22%) | called by muse, mutect2, varscan2
- RFTN2 | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 52/215 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- RGS1 | c.46G>C p.G16R | Missense Mutation (SNP) | VAF 34/274 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.066); called by muse, varscan2
- RGS22 | c.1535C>A p.T512N | Missense Mutation (SNP) | VAF 130/329 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RGS3 | c.1484G>T p.G495V (on ENST00000350696 / NM_001282923.2; = p.G383V on NM_017790.4) | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.28); called by muse, mutect2
- RHAG | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 217/960 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- RNF138 | c.418G>T p.D140Y | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- ROBO1 | c.949A>G p.I317V | Missense Mutation (SNP) | VAF 44/209 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- ROCK1 | c.3463G>A p.D1155N | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, varscan2
- RUNDC1 | c.1516G>T p.G506* | Nonsense Mutation (SNP) | VAF 46/254 reads (18%) | called by muse, mutect2, varscan2
- RUNX1 | c.473A>T p.Q158L (on ENST00000344691 / NM_001001890.3; = p.Q185L on NM_001754.5) | Missense Mutation (SNP) | VAF 114/586 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- RYR2 | c.4622C>A p.P1541H | Missense Mutation (SNP) | VAF 24/233 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RYR2 | c.8458G>A p.G2820S | Missense Mutation (SNP) | VAF 82/624 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- RYR2 | c.8585C>T p.S2862F | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2
- SAG | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCIN | c.446G>T p.R149I | Missense Mutation (SNP) | VAF 124/601 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN10A | c.5761T>A p.Y1921N | Missense Mutation (SNP) | VAF 110/686 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SCN1A | c.34G>T p.D12Y | Missense Mutation (SNP) | VAF 54/335 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCN2A | c.4862C>A p.S1621Y | Missense Mutation (SNP) | VAF 77/505 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SCN4A | c.2089G>T p.V697L | Missense Mutation (SNP) | VAF 49/186 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- SCN7A | c.2686C>A p.H896N | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- SCN9A | c.505G>T p.V169L | Missense Mutation (SNP) | VAF 42/346 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- SEM1 | c.81G>T p.W27C | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- SEMA3D | c.1189A>T p.T397S | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- SEMA6C | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 62/505 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- SEPHS1 | c.82G>T p.G28C | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SEPTIN7 | c.680A>T p.E227V | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- SERPINA12 | c.84G>T p.R28S | Missense Mutation (SNP) | VAF 134/406 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SERPINB12 | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERPINB13 | c.728G>T p.S243I | Missense Mutation (SNP) | VAF 44/237 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- SETBP1 | c.3369G>T p.M1123I | Missense Mutation (SNP) | VAF 85/522 reads (16%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- SETBP1 | c.3370G>T p.G1124C | Missense Mutation (SNP) | VAF 85/523 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SGIP1 | c.229-2A>T p.X77_splice | Splice Site (SNP) | VAF 35/288 reads (12%) | called by muse, mutect2, varscan2
- SH3PXD2B | c.1570C>G p.P524A | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SHOC1 | c.3920C>G p.P1307R | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- SLC14A2 | c.1214C>A p.A405D | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- SLC34A1 | c.1765C>A p.L589M | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- SLC35G1 | c.409G>A p.G137R (on ENST00000427197 / NM_001134658.3; = p.G136R on NM_153226.4) | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC38A3 | c.1145C>T p.P382L | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
485 further variants in this file (108 protein-altering or splice-affecting, 239 silent, 138 other) are not listed here.
